Gene-level copy-number profile of tumor specimen TCGA-43-8118-01A from TCGA case TCGA-43-8118, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 55.4 years (20,224 days).
Specimen TCGA-43-8118-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.f3d2a791-eb65-4d7c-933b-6a2672cfd76b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-43-8118-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9a7f15c4-4b84-492a-86f5-bf2e41616707

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 481; copy number 1: 20,324; copy number 2: 31,226; copy number 3: 5,462; copy number 4: 1,444; copy number 5: 781; copy number 6: 57; copy number 10: 8; copy number 11: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-43-8118-01A-11D-2391-01): tumor purity 0.33, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 481 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:46,723,830–46,724,408, 1 gene: RAC1P2.
- chr4:187,746,094–190,092,279, 51 genes: ADAM20P3, AC108073.3, AC108073.1, ZFP42, TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P, LINC01262, AF250324.1, RNU1-51P, FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr5:141,136,683–141,261,364, 22 genes (within-gene range 0–1): AC244517.11, PCDHB6, PCDHB17P, AC244517.12, PCDHB7, PCDHB8, AC244517.8, PCDHB16, AC244517.6, AC244517.4, PCDHB9, AC244517.7, PCDHB10, PCDHB11, PCDHB12, PCDHB13, PCDHB14, AC244517.10, PCDHB18P, PCDHB19P, PCDHB15, AC244517.3.
- chr6:156,776,020–157,210,779, 1 gene (within-gene range 0–1): ARID1B.
- chr6:156,976,294–157,119,706, 2 genes: AL162578.1, AL049820.1.
- chr6:165,327,287–170,738,536, 129 genes (broad region; genes not listed).
- chr8:150,584–2,926,689, 57 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.
- chr8:6,473,845–6,474,288, 1 gene: AC016065.2.
- chr9:21,106,543–23,438,700, 58 genes: IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1.
- chr9:38,643,042–43,045,120, 122 genes (broad region; genes not listed).
- chr10:36,432,882–36,995,585, 9 genes: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2.
- chr10:37,135,237–37,242,049, 2 genes: RNU6-811P, AL157387.1.
- chr11:5,596,725–5,644,398, 2 genes (within-gene range 0–2): TRIM6-TRIM34, TRIM34.
- chr15:70,654,554–70,778,868, 4 genes (within-gene range 0–2): UACA, AC009269.2, AC009269.5, AC009269.3.
- chr17:53,681,630–53,825,193, 3 genes: AC034268.1, RPS2P48, KIF2B.
- chr18:71,137,829–71,237,158, 3 genes (within-gene range 0–2): AC091691.3, AC091691.2, AC091691.1.
- chr18:77,863,464–78,140,887, 5 genes: RNA5SP461, LINC01029, AC134978.1, RNU6-655P, AC107892.1.
- chr21:19,893,113–19,900,043, 1 gene: LINC01683.
- chr21:23,352,929–23,890,541, 8 genes: D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2, AP000474.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 876 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:85,799,987–86,496,996, 8 genes, copy number 10: CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070.
- chr3:96,244,732–101,861,022, 111 genes, copy number 5 (broad region; genes not listed).
- chr3:107,104,911–110,727,121, 51 genes, copy number 6: AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17, MYH15, AC069499.1, CIP2A, SNORA70, AC069499.2, DZIP3, AC092185.1, RETNLB, TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA.
- chr3:166,605,188–198,222,513, 621 genes, copy number 5 (broad region; genes not listed).
- chr4:60,750,575–60,922,684, 3 genes, copy number 5: LINC02496, AC105420.1, MIR548AG1.
- chr4:77,157,207–77,433,388, 4 genes, copy number 6 (within-gene range 2–6): CCNG2, AC008638.3, AC008638.2, AC008638.1.
- chr4:93,820,171–93,830,964, 2 genes, copy number 6: RNA5SP164, ATOH1.
- chr5:52,282,567–52,959,209, 6 genes, copy number 5 (within-gene range 1–5): RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2.
- chr8:32,911,493–34,346,731, 30 genes, copy number 11: RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3.
- chr20:54,859,688–55,075,140, 2 genes, copy number 5: RNU4ATAC7P, RPL12P4.
- chr22:25,742,144–26,031,045, 1 gene, copy number 5 (within-gene range 3–5): MYO18B.
- chr22:25,876,854–27,061,247, 37 genes, copy number 5: MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2.

Autosomal genes at a single copy (total copy number 1): 19,352. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
